Surgical pathology report (de-identified scan), TCGA case TCGA-TM-A7C3, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site The University of New South Wales, specimen TCGA-TM-A7C3-01A (Primary Tumor).

Specimen: Tissue	D.O.B:	Sex:
Collected:	Location:	

CLINICAL:

No clinical history provided.

MACROSCOPIC:

Specimen labelled "Brain tumour" consists of multiple fragments of pale grey/tan tissue ranging from 1-7mm in maximal dimension, 15 x 15 x 5mm in aggregate. AE one block.

MICROSCOPIC: (Reported by

Sections show fragments of hypercellular, diffusely infiltrating, intrinsic glial tumour (GFAP+) exhibiting mild to moderate nuclear pleomorphism and up to 3 mitoses per high power field. The proliferation index by Ki67 staining is approximately 5%. No endothelial cell swelling or intrinsic necrosis is present.

Foci of psammomatous calcification are seen.

These features are consistent with a histological diagnosis of **anaplastic astrocytoma, WHO Grade III.**

The presence of normal neurones (NeuN+) and reactive astrocytes in the background indicates the tumour is infiltrating cerebral cortex.

COMMENT:

The histological diagnosis of anaplastic astrocytoma is given without knowledge of the clinical or radiological findings.

ICD-O-3

Astrocytoma, grade II 9401/3

Site C6CF Brain, supratentorial NOS C71.0

path Brain NOS C71.9

9/25/13

Distribution:

Source: NCI Genomic Data Commons file bd437984-8dc7-4874-917c-25f45c4b43e2 (TCGA-TM-A7C3.8716B17F-6119-4999-8F12-F9C123FEA60F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).